HCMI case HCM-BROD-1131-C06 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Other and unspecified parts of mouth. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/be13c558-9f05-46c5-9dd3-b45050a5bb12

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1939; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; ICD-10 code: C06.0; Tissue or organ of origin: Mouth, NOS; Site of resection or biopsy: Cheek mucosa; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 76.7 years (28,032 days); AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: MX; Tumor grade: G2; Prior malignancy: no; Prior treatment: No; Residual disease: R0; Tumor depth: 4 mm; Tumor focality: Unifocal.
   Pathology details: Additional pathology findings: Keratinizing dysplasia, moderate; Lymph nodes positive: 0; Lymph nodes tested: 0; Lymphatic invasion present: No; Perineural invasion present: No; Tumor largest dimension diameter: 2 cm; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days; Margin distance: 2.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (1 entry)
- Days to follow up: 2,009 days (5.5 years); Disease response: Complete Response; Progression or recurrence: No.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 74 kg; Height: 160 cm; BMI: 29.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Tobacco smoking quit year: 1988; Alcohol intensity: Occasional Drinker; Alcohol drinks per day: 2.
- Alcohol type: Liquor.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (1 sample)
- Sample HCM-BROD-1131-C06-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 13.
